CCDI case PBCGTA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/9a86c88e-7ea0-4362-8aba-a17f3c5e93de

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Eye, NOS; Age at diagnosis: 1.0 years (352 days).

Biospecimens (3 samples)
- Sample 0DS28N: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DS290: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DS29R: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
